Surgical pathology report (de-identified scan), TCGA case TCGA-AY-4071, project TCGA-COAD (Colon Adenocarcinoma), tissue source site UNC, specimen TCGA-AY-4071-01A (Primary Tumor).

[page 1 of 7]
SURGICAL PATHOLOGY

Surgical Pathology Report

Diagnosis:

FSA, A: Vaginal mucosal, posterior, biopsy
- Benign vaginal squamous mucosa and submucosal stroma, no carcinoma identified.

B: Ovary, left, oophorectomy
- Benign cysts, no carcinoma identified.

C: Ovary, right, oophorectomy
- Benign cysts, no carcinoma identified.

D: Colon, distal sigmoid and rectum, lower anterior resection
Tumor Histologic Type: Adenocarcinoma

Histologic Grade: Moderately differentiated

Depth of Invasion: Into submucosa.
Muscularis propria present, not involved by invasive carcinoma.

Lymphatic Invasion: Not identified

Venous Invasion: Not identified

Perineural invasion: Not identified

Margins:

Proximal margin: Negative
Distal margin: Negative

[page 2 of 7]
Circumferential (radial) margin: Negative
Distance to closest margin: 2.0 cm (distal)

Regional lymph nodes: 0/4

Additional pathologic findings: None

AJCC Stage: pT1 pN0 pMx

Note: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

E: Colon, terminal ileum and proximal right, resection
- Adenomatous polyps (tubular adenomas) (4), surgical margins not involved.
- No invasive carcinoma identified.
- Lymph nodes, pericolic no metastatic carcinoma identified (0/8).

Intraoperative Consult Diagnosis:
Frozen section was requested by [REDACTED]

FSA1: Vagina, posterior, biopsy
- Squamous lined fibrous nodule
- No carcinoma identified

Frozen Section Pathologist:

Clinical History:
rectal moderately differentiated adenocarcinoma, also tubulovillous adenoma in cecum

Gross Description:
Specimen A was received fresh for frozen section, labeled "posterior vaginal mucosa nodule for frozen section" and consists of a 1.5 x 0.7 cm red/tan soft tissue fragment. The specimen is bisected and submitted for frozen section in block FSA1, NTR.

Specimen B is received in a formalin-filled container labeled "left ovary" and consists of a 21.3 gram, 3.5 x 2.5 x 2.3 cm multicystic

[page 3 of 7]
ovary. The external surface is thin, smooth and almost translucent pale tan. The cut surface shows cystic multicystic structures filled with clear serous fluid. There is a small amount of fallopian tube which measures 2.5 cm in length and 0.6 cm in cross sectional diameter. Representative sections of ovary and tube are submitted in blocks B1 and B2.

Specimen C is received in a formalin-filled container labeled "right ovary" and consists of a 33.0 gm, 5.0 x 4.0 x 4.0 cm multicystic ovary. The external surface of the ovary shows a large translucent cystic structure. The ovary is bivalved to reveal a cystic structure filled with clear serous fluid. There is a small segment of fallopian tube, which measures 2.5 cm in length and 0.5 cm in cross sectional diameter. Representative sections of ovary and tube are submitted in blocks C1 and C2.

Specimen D:

Specimen fixation: Formalin

Parts of bowel received: Distal sigmoid colon and rectum with a portion of perianal skin

Specimen length: 26.0 cm and up to 6.0 cm in open circumference

Orientation: Inking: proximal/green, stitch marking distal anterior/red, bowel length/yellow

Tumor location: Distal anterior

Gross appearance of tumor: There is a superficial granular fungating area, which measures 3.0 x 3.0 cm. In the center of this area is a surgical defect where probable tissue procurement occurred in the operating room. This defect is inked with blue ink.

Tumor dimensions: 3.0 x 3.0 x 0.5 cm.

Circumferential growth: Approximately 50% of luminal circumference involved.

[page 4 of 7]
Gross depth of invasion: Tumor grossly appears to invade the submucosa but not through the muscularis propria.

Gross evidence of perforation through visceral peritoneum:
No

Luminal obstruction: None

Bowel circumference at tumor site: 6.0 cm

Gross distance of tumor from margins: 2.0 cm from distal and 20.5 cm from proximal

Lymph nodes: 21 lymph nodes ranging from 0.1 x 0.1 x 0.1 cm to 1.5 x 1.5 x 1.0 cm in maximum dimension.

Other remarkable findings: In the central area there is a small 3mm polyp which is 12 cm from the distal end and 12 cm from the proximal end.

Tissue submitted for special investigation: Tumor was taken by Dr. in the OR for tissue procurement facility and normal tissue was banked in the gross room for tissue procurement facility.

Digital photograph taken:

Block Summary:

Inking: Distal anterior/red, proximal/green, entire length of bowel/yellow,
defect in central tumor/blue

D1 - Perpendicular sections of distal anterior at site of stitch and also is the closest area to tumor

D2-D4 - Distal margin en face

D5 - Proximal margin en face

D6-D17 - Entire block tumor

D18 - Small polyp

D19 - Representative section of proximal colon

D20 - Two lymph node candidates

D21 - Two lymph node candidates

D22 - Three lymph node candidates

D23 - Three lymph node candidates

D24 - Two lymph node candidates

D25 - Three lymph node candidates

[page 5 of 7]
D26 - Three lymph node candidates
D27 - Two lymph node candidates
D28 - Two lymph node candidates

Specimen E:

Specimen fixation: Formalin

Parts of bowel received: Terminal ileum and proximal right colon

Specimen length: 25.0 cm, 12.0 cm is terminal ileum and 12.0 cm is right colon

Orientation: Inking: terminal ileum resection margin/blue, right colon resection margin/black, inner external surface is green beneath the polyp.

Tumor location: There is a pedunculated polyp in the cecum, which measures 1.5 x 1.5 x 1.0 cm. Two tan/brown granular flat polyps in the right colon, which measures 1.5 x 1.0 x 0.2 cm and 1.2 x 0.8 x 0.1 cm. There is a 4th slightly raised polyp in the right colon, which measures 0.4 cm in diameter.

Gross appearance of tumor: See above.

Tumor dimensions: There is a pedunculated polyp in the cecum, which measures 1.5 x 1.5 x 1.0 cm. Two tan/brown granular flat polyps in the right colon, which measures 1.5 x 1.0 x 0.2 cm and 1.2 x 0.8 x 0.1 cm. There is a 4th slightly raised polyp in the right colon, which measures 0.4 cm in diameter. See above.

Circumferential growth: Approximately 10% of luminal circumference involved.

[page 6 of 7]
Gross depth of invasion: Tumor does not invade the submucosa and is primarily superficial.

Gross evidence of perforation through visceral peritoneum:
No

Luminal obstruction: None

Bowel circumference at tumor site: 10.5 cm

Gross distance of tumor from margins: The polyp in the cecum is 10 cm from the colon and 13.5 cm from the terminal ileum. The closest flat polyp is 6.7 cm from the right colon margin and the other flat polyp is 15.0 cm from the terminal ileum margin. The smallest slightly raised polyp is 2.0 cm from the right colon margin.

Lymph nodes: 15 lymph nodes, ranging from 1 x 1 x 1 mm to 1.5 x 1.0 x 1.0 cm in maximum dimension.

Other remarkable findings: The appendix is attached and appears grossly unremarkable and measures 6.0 cm in length and up to 0.8 cm from cross sectional diameter. There is also a blue discoloration at the right colon margin which is 1.0 cm from the margin. This area is either possible tattooing or submucosal hemorrhage. Both of these areas are submitted (E12-E14).

Tissue submitted for special investigation: none

Digital photograph taken: no

Block Summary:

Inking: terminal ileum resection margin/blue, right colon resection margin/black, inner external surface is green beneath the polyp

[page 7 of 7]
E1 - Terminal ileum en face
E2-E3 - Right colon margin en face
E4 - Tip of appendix, bisected
E5 - Representative cross sections of appendix
E6-E8 - Polyps in the cecum, entirely submitted
E9 - The largest flat polyp
E10 - Smallest raised polyp
E11 - Second flat polyp
E12-E14 - Discolorations in the right colon
E14 - Representative section of terminal ileum
E16 - Representative section of normal right colon
E17 - One lymph node, bisected
E18 - One lymph node, bisected
E19 - Two lymph nodes
E20 - One lymph node, bisected
E21 - Three lymph node candidates
E22 - Three lymph node candidates
E23 - Two lymph node candidates
E24 - Three lymph node candidates

P.A.:

Light Microscopy:

Light microscopic examination is performed by [REDACTED]

The frozen section diagnosis is confirmed. Multiple sections show invasion into submucosa. No sections show MP invasion.

Source: NCI Genomic Data Commons file 2ea122f2-107f-4002-820b-a9257858cfa5 (TCGA-AY-4071.C88FF2B7-B266-4A24-8BC5-B5C6335DA220.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).